Gene-level copy-number profile of tumor specimen TCGA-97-8177-01A from TCGA case TCGA-97-8177, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 59.3 years (21,648 days).
Specimen TCGA-97-8177-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.f3f4dcb3-0af7-4a61-9808-131e3a5696f8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-97-8177-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7242593a-0265-4dc0-8ff9-6b56fa8a3b3d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 15,194; copy number 2: 34,130; copy number 3: 8,317; copy number 4: 1,464; copy number 5: 255; copy number 6: 133; copy number 7: 90; copy number 8: 31; copy number 9: 21; copy number 10: 90; copy number 11: 91.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-97-8177-01A-11D-2283-01): tumor purity 0.25, ploidy 3.13, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 711 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:4,175,528–7,769,706, 56 genes, copy number 5–7 (within-gene range 3–7): EEF1DP6, LINC01777, AL355602.1, Z98747.1, LINC01646, AJAP1, Z98886.1, BX005132.1, LINC02781, LINC02782, AL139823.1, Z98259.3, Z98259.2, Z98259.1, Z97988.2, AL365255.1, Z97988.1, MIR4689, NPHP4, KCNAB2, CHD5, AL031847.1, RPL22, RNF207-AS1, RNF207, ICMT, LINC00337, HES3, GPR153, ACOT7, AL031848.2, HES2, ESPN, MIR4252, AL031848.1, TNFRSF25, PLEKHG5, NOL9, RNU6-731P, AL591866.1, TAS1R1, ZBTB48, KLHL21, PHF13, THAP3, DNAJC11, LINC01672, AL591163.1, CAMTA1-DT, CAMTA1, AL590128.1, AL512330.1, RNU1-8P, CAMTA1-IT1, CAMTA1-AS2, CAMTA1-AS1.
- chr1:39,838,110–39,969,968, 7 genes, copy number 5: TRIT1, Y_RNA, MYCL, MYCL-AS1, Y_RNA, MFSD2A, AL663070.1.
- chr5:170,639,158–171,457,626, 18 genes, copy number 8: KCNIP1-AS1, AC008514.1, GABRP, RANBP17, RN7SL623P, AC008514.2, USP12P1, AC091980.2, TLX3, AC091980.1, RN7SL339P, RPSAP71, SNORA70J, RPL10P8, MIR3912, NPM1, FGF18, AC093246.1.
- chr5:172,609,094–177,312,757, 126 genes, copy number 5–6 (broad region; genes not listed).
- chr6:132,296,055–141,486,412, 169 genes, copy number 7–10 (within-gene range 3–10) (broad region; genes not listed).
- chr6:152,898,047–153,427,154, 11 genes, copy number 6: TUBB4BP7, AL080276.1, FBXO5, AL080276.2, MTRF1L, RGS17, RNA5SP224, AL590867.1, AL590867.2, AL358134.1, RNA5SP225.
- chr6:153,938,433–153,938,992, 1 gene, copy number 5: HMGB3P19.
- chr12:66,767–1,495,933, 29 genes, copy number 5: IQSEC3, AC026369.3, AC026369.1, AC026369.2, AC007406.3, SLC6A12, AC007406.1, SLC6A12-AS1, SLC6A13, AC007406.2, AC007406.4, KDM5A, CCDC77, B4GALNT3, NINJ2, AC006205.2, RNU7-103P, AC006205.1, NINJ2-AS1, LINC02455, WNK1, RNU4ATAC16P, AC004765.1, RAD52, AC004803.1, ERC1, HTR1DP1, AC004672.1, AC004672.2.
- chr12:60,092,864–72,186,618, 232 genes, copy number 5–11 (broad region; genes not listed).
- chr12:72,249,964–72,276,954, 1 gene, copy number 6: TRHDE-AS1.
- chr16:46,469,341–48,363,122, 48 genes, copy number 5 (within-gene range 3–5): ANKRD26P1, RNU6-845P, AC092368.2, AC092368.1, SHCBP1, AC092368.3, RAB43P1, AC012186.1, VPS35, AC012186.2, AC012186.3, ORC6, MYLK3, AC007225.1, C16orf87, CKBP1, AC007225.2, GPT2, DNAJA2, AC018845.3, AC018845.1, AC018845.2, NETO2, ITFG1-AS1, RPL23AP72, ITFG1, AC007494.2, AC007494.3, AC007494.1, AC007533.1, Y_RNA, 5S_rRNA, PHKB, RNA5SP425, AC007599.2, AC007599.1, EIF4BP5, NDUFA5P11, LINC02133, AC141846.1, LINC02192, LINC02134, AC096996.3, AC096996.1, ABCC12, AC096996.2, ABCC11, LONP2.
- chr18:47,390–515,294, 13 genes, copy number 5: TUBB8B, AP001005.3, IL9RP4, AP001005.2, ROCK1P1, MIR8078, USP14, THOC1, AP000845.1, AP000915.1, COLEC12, AP000915.2, LINC01925.

Autosomal genes at a single copy (total copy number 1): 15,194. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
